TCGA case TCGA-DD-A73B — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5449c232-56f1-4e03-9421-aba3ae180107

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 72 years; Vital status: Dead; Days to death: 283 days.

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 72.3 years (26,390 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Child pugh classification: B; Ishak fibrosis score: 6 - Established Cirrhosis.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 72.9 years (26,630 days); Days to diagnosis: 240 days; Prior treatment: Yes.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 240 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Liver; Days to recurrence: 240 days.
- Days to follow up: 283 days; Disease response: With Tumor.
- ECOG performance status: 0.

Molecular and laboratory tests
- Alpha Fetoprotein 30 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 6].
- Creatinine 0.9 mg/dL [Blood test normal range lower: 0.6; Blood test normal range upper: 1.1].
- Total Bilirubin 2.1 mg/dL [Blood test normal range lower: 0.1; Blood test normal range upper: 1].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1.1 [Blood test normal range lower: 0.8; Blood test normal range upper: 1.2].
- Albumin 3.5 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].
- Platelets 88 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 450].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Alpha-1 Antitrypsin Deficiency / Gilbert's Syndrome; Viral hepatitis serology tests: Hepatitis B Surface Antigen.
- Timepoint category: Initial Diagnosis; Weight: 74 kg; Height: 154 cm; BMI: 31.2.

Family history
- Relatives with cancer history count: 1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DD-A73B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 150 mg.
  Slide TCGA-DD-A73B-01A-01-TS1: Section location: Top; Percent tumor cells: 96; Percent tumor nuclei: 96; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 2; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-DD-A73B-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DD-A73B-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Multiple.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis B Surface Antigen.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 283 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 283 days; disease-free interval: event (new tumor event after initially disease-free), 240 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 240 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DD-A73B-01A-12D-A32F-01): tumor purity 0.92, ploidy 1.78, whole-genome doublings 0.
